Somatic mutation profile of tumor specimen BA2816D (aliquot aq-BA2816D) from BEATAML1.0 case 2016, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.1 years (7,701 days).
Specimen BA2816D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dba2fee-36f6-439e-b538-1eb7f9fa7773.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2543D (Solid Tissue Normal), aliquot aq-BA2543D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e886dafd-2806-443d-a931-b51c30447b32

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM12 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64103069; called by muse, mutect2
- CSF3R | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV58966685; called by muse, mutect2, varscan2
- RSPH3 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1281004707; called by muse, mutect2, varscan2
- C11orf42 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EVC2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.145); called by muse, mutect2
- EZH2 | c.2217_2218insTCATC p.E740Sfs*24 (on ENST00000460911 / NM_001203247.2; = p.E745Sfs*24 on NM_004456.5) | Frame Shift Ins (INS) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- FAM221B | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH10 | c.3010G>T p.G1004C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF282 | c.1043A>G p.D348G | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZFHX4 | c.1083C>T p.R361= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs781179725; called by muse, mutect2, varscan2
